Somatic mutation profile of tumor specimen TCGA-AX-A1C9-01A (aliquot TCGA-AX-A1C9-01A-11D-A135-09) from TCGA case TCGA-AX-A1C9, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 73.7 years (26,903 days).
Specimen TCGA-AX-A1C9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 117f9443-c760-4e53-8d7a-f7f087a88ff6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A1C9-10A (Blood Derived Normal), aliquot TCGA-AX-A1C9-10A-01D-A135-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/04cba825-3d51-4816-9c66-3882998e3336

The open-access MAF lists 1,145 somatic variants for this specimen: 820 protein-altering or splice-affecting, 306 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 730, Silent 306, Nonsense Mutation 41, Frame Shift Del 17, Splice Site 14, Frame Shift Ins 10, Intron 7, Splice Region 7, RNA 5, 5'Flank 4, 3'UTR 2, 3'Flank 1.

Variants (750 of 1,145; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA1 | c.2810C>T p.A937V | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs137854495, CM990007, COSV101036930; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP6V1B1 | c.785+1G>A p.X262_splice | Splice Site (SNP) | VAF 9/45 reads (20%) | catalogued as rs727504746, CS991327, COSV52268252, COSV99314101; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CACNA1F | c.1309+1G>A p.X437_splice | Splice Site (SNP) | VAF 18/49 reads (37%) | catalogued as rs782575860, COSV59904308; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CIC | c.452+1G>A p.X151_splice | Splice Site (SNP) | VAF 16/29 reads (55%) | hotspot (GDC flag); catalogued as COSV50552879, COSV50704605; called by muse, mutect2, varscan2
- CSTB | c.202C>T p.R68* | Nonsense Mutation (SNP) | VAF 18/43 reads (42%) | catalogued as rs74315442, CM960424; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 32/82 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs121913412, COSV62687862, COSV62689580, COSV62714770; ClinVar: conflicting interpretations of pathogenicity / pathogenic /  other / likely pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.2264T>C p.L755S | Missense Mutation (SNP) | VAF 15/36 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913470, COSV54062780, COSV54064269; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.2524G>A p.V842I | Missense Mutation (SNP) | VAF 8/22 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1057519738, COSV104371920, COSV54062791; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 34/98 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KIT | c.1879+1G>A p.X627_splice | Splice Site (SNP) | VAF 46/114 reads (40%) | catalogued as rs794726675, CS920766, COSV55413993; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LEP | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs104894023, CM981200, COSV58240705, COSV58240868; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MAX | c.83A>G p.H28R | Missense Mutation (SNP) | VAF 58/146 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV52415800; called by muse, mutect2, varscan2
- MSH6 | c.1483C>T p.R495* | Nonsense Mutation (SNP) | VAF 24/65 reads (37%) | catalogued as rs587779212, CM105419, COSV52273723; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.3261dup p.F1088Lfs*5 | Frame Shift Ins (INS) | VAF 14/56 reads (25%) | hotspot (GDC flag); catalogued as rs267608078; ClinVar: pathogenic; called by mutect2, varscan2
- MYH7 | c.2609G>A p.R870H | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs36211715, CM1412215, CM952025, COSV62524343; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NCF2 | c.550C>T p.R184* | Nonsense Mutation (SNP) | VAF 30/72 reads (42%) | catalogued as rs766745748, CM101806, COSV100838886; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NIPAL4 | c.688G>A p.G230R | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370356566, CM074276; ClinVar: pathogenic; called by muse, mutect2, varscan2
- OLFML2B | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs142806829, COSV99668420; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PEX6 | c.2578C>T p.R860W | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs61753230, CM091387, COSV99769527; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1634A>C p.E545A | Missense Mutation (SNP) | VAF 32/87 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs121913274, CM130273, COSV55873209, COSV55873220, COSV55892885; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 27/62 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs121913294, CM074465, CM102472, COSV100911374, COSV64288961, COSV64302184; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 50/142 reads (35%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, varscan2
- PTEN | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.116); catalogued as rs587782350, CM991083, COSV64291511, COSV64305247; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- PYGM | c.1136C>T p.T379M | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1131691807, CM071956, COSV99377090; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RAG1 | c.1681C>T p.R561C | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); catalogued as rs104894285, CM981695; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RUNX1 | c.530G>A p.R177Q (on ENST00000344691 / NM_001001890.3; = p.R204Q on NM_001754.5) | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1569061762, CM093278, COSV55866469, COSV55875660, COSV55875973; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SCN4A | c.3938C>T p.T1313M | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs121908547, CM941270, COSV71127251; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC5A7 | c.1082G>A p.R361Q | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.701); catalogued as rs147656110, COSV50902580; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TFR2 | c.1186C>T p.R396* | Nonsense Mutation (SNP) | VAF 11/29 reads (38%) | catalogued as rs80338882, CM065476, COSV99774512; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 23/61 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 18/53 reads (34%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.14333C>A p.A4778D | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV68947964; called by muse, mutect2, varscan2
- ABCA3 | c.3520C>T p.R1174W | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs112168649, COSV100068435; called by muse, varscan2
- ABCB7 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.116); catalogued as COSV53723803; called by muse, mutect2, varscan2
- ABCD3 | c.1451G>A p.R484H | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs937581676, COSV100931374; called by muse, mutect2, varscan2
- ABL1 | c.1850G>A p.R617H | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59328408; called by muse, mutect2, varscan2
- AC004922.1 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV99402916; called by muse, mutect2, varscan2
- ACBD3 | c.429-1G>T p.X143_splice | Splice Site (SNP) | VAF 42/75 reads (56%) | catalogued as COSV100830994, COSV100831108; called by muse, mutect2, varscan2
- ACIN1 | c.1339del p.A447Lfs*19 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as rs879396950, COSV52972585; called by mutect2, varscan2
- ACSM4 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.789); catalogued as COSV101257147; called by muse, mutect2, varscan2
- ACTL9 | c.1231G>A p.V411M | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs782060616, COSV61005266; called by muse, mutect2, varscan2
- ACTN2 | c.745G>A p.V249I | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as rs771260546, COSV63971557; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAM19 | c.1424G>A p.R475H | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1282398094, COSV99977103; called by muse, mutect2, varscan2
- ADAM21 | c.2051del p.L684Cfs*3 | Frame Shift Del (DEL) | VAF 17/54 reads (31%) | catalogued as rs546931496; called by mutect2, pindel, varscan2
- ADAMTS10 | c.2440C>T p.R814C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV99546887; called by mutect2, varscan2
- ADCY5 | c.2116G>A p.A706T | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs376898099, COSV59199728; called by muse, mutect2, varscan2
- ADCY6 | c.3359C>T p.T1120M | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100326616; called by muse, mutect2, varscan2
- ADGRB3 | c.1177A>G p.N393D | Missense Mutation (SNP) | VAF 53/170 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as COSV65409348; called by muse, varscan2
- ADGRG4 | c.3941C>T p.S1314L | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs751562884, COSV54950446; called by muse, mutect2, varscan2
- ADGRV1 | c.12637G>A p.E4213K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs397517421, COSV67979356; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADRA2B | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1441656343, COSV101337359; called by muse, mutect2
- AFDN | c.1142C>T p.P381L | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs200779172, COSV100652967; called by muse, mutect2, varscan2
- AFF1 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs1300205226, COSV57125483; called by muse, mutect2, varscan2
- AFF2 | c.2777G>A p.R926H | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs782499369, COSV53987532, COSV54007591; called by muse, mutect2, varscan2
- AGAP3 | c.1724T>C p.V575A (on ENST00000622464; = p.V611A on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); catalogued as COSV101257159; called by muse, mutect2
- AGO1 | c.2275C>T p.R759* | Nonsense Mutation (SNP) | VAF 19/41 reads (46%) | catalogued as COSV64596680; called by muse, mutect2, varscan2
- AHCTF1 | c.2104G>A p.A702T (on ENST00000366508; = p.A676T on NM_015446.5) | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.147); catalogued as rs1357741661, COSV100403653; called by muse, mutect2, varscan2
- AKNA | c.3335G>A p.R1112H | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs780532577, COSV99800301; called by muse, varscan2
- AL592490.1 | c.1685C>T p.A562V | Missense Mutation (SNP) | VAF 25/30 reads (83%) | SIFT tolerated (0.05); PolyPhen benign (0.265); catalogued as COSV101308191; called by muse, mutect2, varscan2
- ALAS1 | c.1501C>T p.R501C | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs891809385, COSV59629676; called by muse, mutect2, varscan2
- ALDH18A1 | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.219); catalogued as rs755594128, COSV100973165; called by muse, mutect2, varscan2
- ALDH1A2 | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1179037754, COSV99990713; called by muse, mutect2, varscan2
- ALDH1B1 | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs756342967, COSV100890936; called by muse, mutect2, varscan2
- ALMS1 | c.11945G>A p.G3982D | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1449622209, COSV100042402; called by muse, mutect2, varscan2
- ALPG | c.451G>A p.V151M | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs372574780, COSV99779310; called by muse, mutect2, varscan2
- ALPK3 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99360874; called by muse, mutect2, varscan2
- AMY2A | c.1205G>A p.R402Q | Missense Mutation (SNP) | VAF 117/625 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758134251, COSV101340634, COSV101340678; called by muse, mutect2, varscan2
- ANAPC1 | c.2888G>A p.R963H | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1246645700; called by mutect2, varscan2
- ANK1 | c.4001G>T p.R1334L | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV99225196; called by muse, mutect2, varscan2
- ANKRD13B | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); catalogued as rs755340913, COSV101198899; called by muse, mutect2, varscan2
- ANKRD27 | c.1088G>A p.R363Q | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.687); catalogued as rs140541725; called by muse, mutect2, varscan2
- ANO4 | c.1748G>A p.R583H (on ENST00000392977 / NM_001286615.2; = p.R548H on NM_178826.4) | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767411991, COSV100152835, COSV54614139; called by muse, mutect2, varscan2
- ANOS1 | c.1826C>T p.S609F | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99390864; called by muse, mutect2, varscan2
- AOC1 | c.1447G>A p.G483S | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs894375698, COSV100710760; called by muse, mutect2, varscan2
- AP4M1 | c.1085G>A p.R362H | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs764352275, COSV100384888; called by muse, varscan2
- APAF1 | c.1822C>T p.R608C (on ENST00000551964 / NM_181861.2; = p.R597C on NM_001160.3) | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs916104396, COSV100244086; called by muse, mutect2, varscan2
- APH1A | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0.033); catalogued as rs782641325, COSV99354203; called by muse, mutect2, varscan2
- APMAP | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV54172425; called by muse, mutect2, varscan2
- APOBEC3D | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745893074, COSV99328937; called by muse, mutect2, varscan2
- APOBEC3G | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.849); catalogued as rs200526446, COSV101349074; called by muse, mutect2, varscan2
- ARFGEF3 | c.2420G>A p.S807N | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.631); catalogued as COSV99292616, COSV99293422; called by muse, mutect2, varscan2
- ARFIP2 | c.664C>A p.L222I | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.603); catalogued as COSV99601523; called by muse, mutect2, varscan2
- ARFRP1 | c.412G>A p.V138M | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.048); catalogued as COSV99422971; called by muse, mutect2, varscan2
- ARHGAP35 | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.614); catalogued as COSV101351027, COSV68331555; called by muse, mutect2, varscan2
- ARHGAP35 | c.3479C>T p.T1160M | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.344); catalogued as rs531784492, COSV101351028; called by muse, mutect2, varscan2
- ARHGAP35 | c.3949G>A p.V1317M | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV68330140, COSV68330679; called by muse, mutect2, varscan2
- ARHGAP44 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778494505, COSV99310652; called by muse, mutect2, varscan2
- ARHGEF17 | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.161); catalogued as rs1439459860, COSV55229061, COSV99734802; called by muse, mutect2, varscan2
- ARHGEF28 | c.4859C>T p.S1620L | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1173768297, COSV99709023; called by muse, mutect2, varscan2
- ARHGEF6 | c.953G>A p.G318D | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1569402435, COSV99166458; called by muse, mutect2, varscan2
- ARID4B | c.815A>G p.D272G | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.212); catalogued as COSV99935597; called by muse, mutect2, varscan2
- ARID5B | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99689645; called by muse, mutect2, varscan2
- ARIH2 | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV100711307; called by muse, mutect2, varscan2
- ARMC2 | c.1606G>A p.V536I | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT tolerated (0.58); PolyPhen benign (0.03); catalogued as rs373141097; called by muse, mutect2, varscan2
- ARV1 | c.518del p.K173Sfs*8 | Frame Shift Del (DEL) | VAF 19/72 reads (26%) | catalogued as rs544784472, COSV59618356; called by mutect2, varscan2
- ASAP3 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1229700736, COSV100369425; called by muse, mutect2, varscan2
- ASIC2 | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as rs1481256687, COSV63314312; called by muse, mutect2, varscan2
- ASTN1 | c.2557G>A p.G853S | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs866121483, COSV56063542; called by muse, mutect2, varscan2
- ATAD3B | c.394C>T p.R132C (on ENST00000308647; = p.R238C on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/69 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs757344083, COSV100426461, COSV58020515; called by muse, mutect2, varscan2
- ATF5 | c.109del p.L37Wfs*31 | Frame Shift Del (DEL) | VAF 12/22 reads (55%) | catalogued as rs768611141; called by mutect2, varscan2
- ATM | c.2603A>G p.D868G | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.197); catalogued as rs750322758, COSV99589570; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP10B | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1242354342, COSV100469391; called by muse, mutect2, varscan2
- ATP11B | c.334C>T p.R112W | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1441413082, COSV60033955; called by muse, mutect2, varscan2
- ATP1B1 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63170907; called by muse, mutect2, varscan2
- ATP5PB | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs574830737, COSV100867636; called by muse, mutect2, varscan2
- ATP8B4 | c.1538G>A p.R513Q | Missense Mutation (SNP) | VAF 37/54 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1376889811, COSV52721344; called by muse, mutect2, varscan2
- ATP8B4 | c.1099C>T p.R367* | Nonsense Mutation (SNP) | VAF 21/35 reads (60%) | catalogued as rs199887907; called by muse, mutect2, varscan2
- ATR | c.7376G>A p.R2459H | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs754253403, COSV63387628; called by muse, mutect2, varscan2
- ATXN2 | c.1729C>T p.R577W (on ENST00000550104; = p.R417W on NM_002973.4) | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs889126294, COSV101112749; called by muse, mutect2, varscan2
- ATXN2L | c.1862C>T p.P621L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV100294279; called by muse, mutect2
- AWAT2 | c.194G>T p.R65L | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as COSV99339653; called by muse, varscan2
- AXL | c.874dup p.H292Pfs*47 | Frame Shift Ins (INS) | VAF 10/28 reads (36%) | catalogued as rs778012871; called by mutect2, varscan2
- BABAM2 | c.481A>G p.K161E | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.187); catalogued as COSV59620972; called by muse, mutect2, varscan2
- BCR | c.3284C>T p.A1095V | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV59934054; called by muse, mutect2, varscan2
- BDH1 | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 30/45 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs768985550, COSV100827129; called by muse, mutect2, varscan2
- BPHL | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs1479493437, COSV100984472; called by muse, mutect2, varscan2
- BSPRY | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200697650, COSV100949523; called by muse, mutect2, varscan2
- BTAF1 | c.3511+1G>A p.X1171_splice | Splice Site (SNP) | VAF 21/62 reads (34%) | catalogued as COSV99795314; called by muse, mutect2, varscan2
- BTBD2 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV99724717; called by muse, mutect2, varscan2
- BTBD3 | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1237891192, COSV54781123, COSV99655857; called by muse, mutect2, varscan2
- BTK | c.1442G>A p.C481Y | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV58117136, COSV58122516, COSV58122597; called by muse, mutect2, varscan2
- BTK | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100437593; called by muse, mutect2, varscan2
- C19orf57 | c.596C>T p.T199M | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.157); catalogued as rs147137336; called by muse, varscan2
- C1QL4 | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99226833; called by muse, mutect2, varscan2
- C1orf53 | c.314C>T p.T105I | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100956442; called by muse, mutect2, varscan2
- C3orf20 | c.1774C>T p.R592W | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as rs752469951, COSV53787262; called by muse, mutect2, varscan2
- C6 | c.828dup p.S277Efs*15 | Frame Shift Ins (INS) | VAF 24/64 reads (38%) | catalogued as rs372345940; called by mutect2, varscan2
- C7orf26 | c.415C>T p.R139W | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1179537009, COSV100732903; called by muse, mutect2, varscan2
- CA4 | c.677C>T p.T226I | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV56281571; called by muse, mutect2, varscan2
- CACNA1D | c.2251G>A p.A751T (on ENST00000350061 / NM_001128840.3; = p.A771T on NM_000720.4) | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99858081; called by muse, mutect2, varscan2
- CACNA1D | c.3751G>A p.E1251K (on ENST00000350061 / NM_001128840.3; = p.E1271K on NM_000720.4) | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99858084; called by muse, mutect2, varscan2
- CACNA1E | c.4348G>T p.A1450S | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV100702535, COSV62381981; called by muse, mutect2, varscan2
- CACNA1F | c.2766G>T p.K922N | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100544777; called by muse, mutect2, varscan2
- CACNA1F | c.1464G>T p.E488D | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.225); catalogued as rs782501197, CM153053, COSV100544778; called by muse, mutect2, varscan2
- CAD | c.3409G>A p.V1137M | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.84); PolyPhen probably damaging (1); catalogued as rs773583200, COSV104391632, COSV99255003; called by muse, mutect2, varscan2
- CALR | c.937G>A p.V313M | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.75); catalogued as rs1026947469, COSV100330681; called by muse, mutect2, varscan2
- CAMSAP3 | c.1793C>T p.S598L | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as rs747388400, COSV50330767; called by muse, varscan2
- CARM1 | c.1522G>A p.G508R | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV53403399, COSV53404905; called by muse, mutect2, varscan2
- CASZ1 | c.559G>A p.G187S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.827); catalogued as rs1344522422, COSV100681332; called by muse, mutect2
- CBLIF | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.658); catalogued as rs777339415, COSV99950938; called by muse, mutect2, varscan2
- CBLL2 | c.814C>G p.P272A | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.093); catalogued as COSV100081590; called by muse, mutect2, varscan2
- CCDC106 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.572); catalogued as rs150361758; called by muse, mutect2, varscan2
- CCDC127 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.806); catalogued as rs559771861, COSV99722994; called by muse, mutect2, varscan2
- CCDC27 | c.1097A>G p.H366R | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV99622463; called by muse, mutect2, varscan2
- CCDC28B | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs895573256, COSV99356560; called by muse, mutect2, varscan2
- CCR6 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs1432942316, COSV59473985; called by muse, mutect2
- CD207 | c.742G>A p.G248R | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.634); catalogued as COSV101338555, COSV69652204; called by muse, mutect2, varscan2
- CD6 | c.1919C>T p.S640L | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.223); catalogued as rs1434446382, COSV100533010; called by muse, mutect2, varscan2
- CD72 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.427); catalogued as rs766540486, COSV52410421; called by muse, mutect2, varscan2
- CD8B | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.035); catalogued as rs751687141, COSV100514501; called by muse, mutect2, varscan2
- CDC42BPB | c.4832C>T p.A1611V | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1339244595, COSV63476637; called by muse, mutect2, varscan2
- CDC42BPB | c.1294C>T p.R432W | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs769595230, COSV63474850; called by muse, mutect2, varscan2
- CDC5L | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101014906, COSV65175715; called by muse, mutect2, varscan2
- CDCA5 | c.322G>A p.V108I | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as rs764770497, COSV99297831; called by muse, varscan2
- CDH22 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754220472, COSV100952846; called by muse, mutect2, varscan2
- CDH24 | c.1193C>T p.A398V | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746379911, COSV57458875; called by muse, mutect2, varscan2
- CDK19 | c.985G>C p.A329P | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100098499; called by muse, mutect2, varscan2
- CDK5 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as rs770442459, COSV99876927; called by muse, varscan2
- CENPE | c.4567A>G p.N1523D | Missense Mutation (SNP) | VAF 79/220 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as COSV99477885; called by muse, mutect2, varscan2
- CENPI | c.2051A>G p.H684R | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV54506813, COSV99515356; called by muse, mutect2, varscan2
- CEP78 | c.1177C>T p.R393C (on ENST00000424347 / NM_001349840.2; = p.R394C on NM_032171.3) | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750484511, COSV52850229; called by muse, mutect2, varscan2
- CERT1 | c.1036C>T p.H346Y (on ENST00000405807 / NM_001130105.1; = p.H218Y on NM_005713.3) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.836); catalogued as COSV99783232; called by muse, mutect2, varscan2
- CFAP100 | c.1621C>T p.R541C | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs764806137, COSV100729215; called by muse, varscan2
- CHD4 | c.3823C>T p.R1275W (on ENST00000357008 / NM_001363606.2; = p.R1288W on NM_001273.5) | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100537832; called by muse, mutect2, varscan2
- CHD4 | c.3275G>A p.R1092Q (on ENST00000357008 / NM_001363606.2; = p.R1105Q on NM_001273.5) | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100537532, COSV100537818, COSV58899203; called by muse, mutect2, varscan2
- CHD8 | c.6733G>T p.G2245C (on ENST00000646647 / NM_001170629.2; = p.G1966C on NM_020920.4) | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.431); catalogued as COSV100765302; called by muse, mutect2, varscan2
- CHN1 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs376266608; called by muse, mutect2, varscan2
- CHRM1 | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.997); catalogued as rs1372342324, COSV100186183; called by muse, mutect2, varscan2
- CHRM3 | c.1085G>T p.R362I | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.506); catalogued as COSV99698331; called by muse, mutect2, varscan2
- CHRNA3 | c.1156G>A p.A386T | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0.005); catalogued as rs200539472, COSV58775282; called by mutect2, varscan2
- CHRNA4 | c.1700C>T p.A567V | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.302); catalogued as rs76895198, COSV64718380; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- CHST8 | c.894G>T p.E298D | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.964); catalogued as COSV99381073; called by muse, mutect2, varscan2
- CHTOP | c.400C>T p.R134* | Nonsense Mutation (SNP) | VAF 12/23 reads (52%) | catalogued as COSV100904652, COSV100904674; called by muse, mutect2, varscan2
- CIC | c.4411C>T p.R1471W | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs778649585, COSV50616500; called by muse, mutect2, varscan2
- CLASRP | c.1718C>T p.T573M | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99673809; called by muse, mutect2, varscan2
- CLCN6 | c.2050A>G p.S684G | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.121); catalogued as COSV100411888; called by muse, mutect2
- CLDN25 | c.99G>A p.W33* | Nonsense Mutation (SNP) | VAF 31/81 reads (38%) | catalogued as COSV101493601; called by muse, mutect2, varscan2
- CLHC1 | c.690dup p.L231Ifs*16 | Frame Shift Ins (INS) | VAF 32/102 reads (31%) | catalogued as rs766798457; called by mutect2, pindel, varscan2
- CLMP | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as rs898341255, COSV101507392; called by muse, mutect2, varscan2
- CLPTM1 | c.362C>T p.T121M | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.193); catalogued as rs1376192635, COSV100493766; called by muse, mutect2, varscan2
- CLTCL1 | c.3211G>A p.V1071I | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs369214595; called by muse, mutect2, varscan2
- CMKLR1 | c.670C>T p.R224C (on ENST00000312143 / NM_001142344.2; = p.R222C on NM_004072.3) | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200653739, COSV100379461; called by muse, mutect2, varscan2
- CNGB3 | c.74G>A p.R25H | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs141098074; called by muse, mutect2, varscan2
- CNNM3 | c.1543C>T p.R515C | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.872); catalogued as rs140550487; called by muse, mutect2
- CNOT9 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 59/153 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55302351; called by muse, mutect2, varscan2
- CNTNAP2 | c.1148A>T p.Y383F | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV100666425; called by muse, mutect2, varscan2
- CNTNAP4 | c.2431G>A p.G811R | Missense Mutation (SNP) | VAF 38/59 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1371162409, COSV56706368; called by muse, mutect2, varscan2
- COBL | c.2152C>T p.R718* | Nonsense Mutation (SNP) | VAF 12/45 reads (27%) | catalogued as rs372919855; called by muse, mutect2, varscan2
- COL18A1 | c.1969G>A p.D657N (on ENST00000359759 / NM_130444.3; = p.D422N on NM_030582.4) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as rs1367224866, COSV100700677; called by muse, mutect2, varscan2
- COL20A1 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV100490525; called by muse, mutect2, varscan2
- COL2A1 | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as rs766480693, COSV100476390; called by muse, mutect2
- COL4A4 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.588); catalogued as COSV100306812; called by muse, mutect2, varscan2
- COL4A5 | c.4304G>A p.R1435H | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1225113105, COSV100087649; called by muse, mutect2, varscan2
- COL5A1 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.994); catalogued as rs1382944823, COSV100879906; called by muse, mutect2, varscan2
- COL6A3 | c.4405G>A p.G1469S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); catalogued as rs771199614, COSV99798186; called by muse, mutect2, varscan2
- COL7A1 | c.3643G>A p.A1215T | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.31); PolyPhen benign (0.417); catalogued as rs865954493, COSV100096185; called by muse, mutect2, varscan2
- COLGALT2 | c.1603G>A p.V535I | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.036); catalogued as rs759172474, COSV100730640; called by muse, mutect2, varscan2
- COPA | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99615531; called by muse, mutect2, varscan2
- COPE | c.635G>A p.C212Y | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99447447; called by muse, mutect2, varscan2
- COPS7A | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99976462; called by muse, mutect2, varscan2
- COQ8B | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs778169057, COSV99699410; called by muse, mutect2, varscan2
- CORO2B | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs753693651, COSV99963242; called by muse, mutect2, varscan2
- COX6B1 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.067); catalogued as rs778559323, COSV99876874; called by muse, varscan2
- COX6C | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.155); catalogued as rs766823907, COSV99881935; called by muse, mutect2
- CRB1 | c.3172G>A p.E1058K | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.7); PolyPhen benign (0.04); catalogued as rs564754426, COSV66328611; called by muse, mutect2, varscan2
- CRB2 | c.1267G>A p.V423I | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs775167408, COSV100749634; called by muse, mutect2, varscan2
- CRYBA1 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs757580467, COSV56601631; called by muse, mutect2, varscan2
- CRYBB1 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.325); catalogued as rs200746178, COSV99316019; called by muse, mutect2, varscan2
- CRYGD | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as rs770342455, COSV100006048; called by muse, mutect2, varscan2
- CSMD1 | c.7189A>G p.T2397A (on ENST00000520002; = p.T2396A on NM_033225.6) | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as COSV100147572; called by muse, mutect2, varscan2
- CTC1 | c.3170G>A p.R1057H | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs776956576, COSV100236422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTSF | c.1141G>A p.V381M | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.599); catalogued as rs757455465, COSV59747341; called by muse, mutect2, varscan2
- CTSG | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.776); catalogued as COSV53534971; called by muse, mutect2, varscan2
- CTSS | c.931C>T p.R311W | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs143154304; called by muse, mutect2, varscan2
- CTTNBP2 | c.947C>T p.A316V | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs779705396, COSV99353906; called by muse, mutect2, varscan2
- CUL9 | c.6376G>A p.G2126R | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.398); catalogued as rs138125607; called by muse, varscan2
- CYP27B1 | c.1214del p.N405Ifs*69 | Frame Shift Del (DEL) | VAF 18/45 reads (40%) | catalogued as COSV56986855; called by mutect2, pindel, varscan2
- CYP2A13 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs745929748, COSV100387017, COSV57838994; called by muse, mutect2, varscan2
- CYP2A6 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.22); catalogued as rs780129128, COSV99991832; called by muse, mutect2, varscan2
- CYP2C19 | c.389C>T p.T130M | Missense Mutation (SNP) | VAF 66/173 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs150152656, CM1510895; called by muse, mutect2, varscan2
- DAO | c.4C>T p.R2C | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs773765064, COSV57324738; called by muse, mutect2
- DCAF5 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as COSV100432465; called by muse, mutect2, varscan2
- DDR2 | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs747307320, COSV100906553, COSV63373949; called by muse, mutect2, varscan2
- DDX11 | c.480+2T>C p.X160_splice | Splice Site (SNP) | VAF 9/32 reads (28%) | catalogued as COSV99299597; called by muse, mutect2, varscan2
- DDX54 | c.1529G>A p.R510H | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as rs545528023, COSV100013861; called by muse, varscan2
- DEFB106A | c.66dup p.D23* | Frame Shift Ins (INS) | VAF 12/84 reads (14%) | catalogued as rs780992152; called by mutect2, varscan2
- DENND11 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV101530711; called by muse, mutect2, varscan2
- DENND1C | c.1486C>T p.R496C | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs376952718; called by muse, mutect2, varscan2
- DGKG | c.1577C>G p.A526G | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99403249, COSV99404551; called by muse, mutect2, varscan2
- DHX8 | c.574C>T p.R192* | Nonsense Mutation (SNP) | VAF 8/21 reads (38%) | catalogued as COSV99292224; called by mutect2, varscan2
- DISP3 | c.1001C>T p.S334L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs759870550, COSV99608548; called by muse, mutect2, varscan2
- DIXDC1 | c.1733G>A p.R578Q (on ENST00000440460 / NM_001037954.4; = p.R367Q on NM_033425.4) | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs370924870, COSV59462146; called by muse, mutect2, varscan2
- DLAT | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs200500508; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- DLGAP1 | c.1082C>T p.T361M | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); catalogued as COSV59784293; called by muse, mutect2, varscan2
- DLGAP3 | c.2453G>A p.R818H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.555); catalogued as rs151019955; called by muse, varscan2
- DMBT1 | c.6080G>A p.R2027H (on ENST00000338354 / NM_001377530.1; = p.R1270H on NM_004406.3) | Missense Mutation (SNP) | VAF 58/179 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768251433, COSV57557328; called by muse, mutect2, varscan2
- DNAH1 | c.5347C>T p.R1783W | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs759947620, COSV101325725; called by muse, varscan2
- DNAH10 | c.1571G>T p.R524M (on ENST00000409039; = p.R463M on NM_207437.3) | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV101292238; called by muse, mutect2, varscan2
- DNAH10 | c.10163T>C p.L3388P (on ENST00000409039; = p.L3327P on NM_207437.3) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101292239; called by muse, mutect2, varscan2
- DNAH17 | c.2765G>A p.R922H | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs534483320, COSV101101082; called by muse, mutect2, varscan2
- DNAH7 | c.6203A>G p.D2068G | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56759831; called by muse, mutect2, varscan2
- DNAH8 | c.4879C>T p.R1627C | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as rs747954312, COSV100543695, COSV100545130; called by muse, mutect2, varscan2
- DNM2 | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1366377441, COSV58972167; called by muse, mutect2, varscan2
- DOCK7 | c.3388C>T p.H1130Y (on ENST00000635253 / NM_001367561.1; = p.H1099Y on NM_033407.3) | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV99224345; called by muse, mutect2, varscan2
- DPAGT1 | c.872C>A p.P291H | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99597976; called by muse, mutect2, varscan2
- DPYD | c.2074C>T p.R692W | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs538703919, COSV100929024, COSV64594793; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DRC3 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769383947, COSV100572715; called by muse, mutect2, varscan2
- DSCAM | c.4763C>T p.T1588M | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.127); catalogued as rs145500496, COSV101260070; called by muse, mutect2, varscan2
- DSCAM | c.2434C>T p.H812Y | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.184); catalogued as COSV101260071; called by muse, mutect2, varscan2
- DSEL | c.332C>A p.P111Q | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59496216; called by muse, mutect2, varscan2
- DTX3 | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54086116; called by muse, mutect2, varscan2
- DYNC2H1 | c.6649C>T p.R2217* | Nonsense Mutation (SNP) | VAF 21/56 reads (38%) | catalogued as rs756087785, COSV100518515; called by muse, mutect2, varscan2
- DYNC2I1 | c.2323G>A p.V775I | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.037); catalogued as rs1261400525, COSV101337666; called by muse, mutect2, varscan2
- DYRK3 | c.1280T>C p.M427T | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as COSV100895686; called by muse, mutect2, varscan2
- ECM2 | c.1709G>A p.R570Q | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); catalogued as rs1234033612, COSV60743243; called by muse, mutect2, varscan2
- EDNRA | c.1256G>A p.R419Q | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs200104039, COSV100163376; called by muse, mutect2, varscan2
- EEF1A1 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV100303307; called by muse, mutect2, varscan2
- EGFLAM | c.2866C>T p.R956W (on ENST00000354891 / NM_001205301.2; = p.R948W on NM_152403.4) | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs539365019, COSV100380266; called by muse, mutect2, varscan2
- EIF4A1 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV99548936; called by muse, mutect2, varscan2
- ELMO1 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1311907939, COSV60313153; called by muse, mutect2, varscan2
- EMILIN2 | c.1151G>A p.R384Q | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as rs778731918, COSV99598495; called by muse, mutect2, varscan2
- ENO3 | c.1067+1G>A p.X356_splice | Splice Site (SNP) | VAF 20/49 reads (41%) | catalogued as rs374679936; called by muse, mutect2, varscan2
- ENPP2 | c.1006G>C p.V336L (on ENST00000075322 / NM_001040092.3; = p.V388L on NM_006209.5) | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV99308255; called by muse, mutect2, varscan2
- EPN1 | c.765G>A p.S255= (on ENST00000270460 / NM_001321263.1; = p.S230= on NM_013333.3) | Splice Region (SNP) | VAF 13/22 reads (59%) | catalogued as rs1195533986, COSV50036372; called by muse, mutect2, varscan2
- ERCC1 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201089019, COSV99185286; called by muse, mutect2, varscan2
- ERICH1 | c.421A>G p.S141G | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.559); catalogued as COSV100032470; called by muse, mutect2, varscan2
- ERMAP | c.796C>T p.R266W | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.162); catalogued as rs772808307, COSV60274321; called by muse, mutect2, varscan2
- ESRP2 | c.1687A>G p.M563V (on ENST00000565858 / NM_001365264.1; = p.M553V on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.81); catalogued as COSV99251273; called by muse, mutect2, varscan2
- ETV1 | c.428C>T p.T143M | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs80157564, COSV99622960; called by muse, mutect2, varscan2
- EXOC5 | c.2083C>T p.R695C | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs868177967, COSV61770140; called by muse, mutect2, varscan2
- EXOSC10 | c.1783C>T p.P595S | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs764579571, COSV58665965; called by muse, varscan2
- EYA1 | c.1703C>T p.A568V | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as rs765493132, COSV58160092; called by muse, mutect2
- FAM102A | c.1069G>A p.D357N (on ENST00000373095 / NM_001035254.3; = p.D215N on NM_203305.2) | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as rs1461397159, COSV100305529; called by muse, mutect2, varscan2
- FAM160A2 | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs760692181, COSV99792053; called by muse, mutect2, varscan2
- FAM160B1 | c.1730C>T p.P577L | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100985425; called by muse, mutect2, varscan2
- FAM20A | c.1333A>G p.I445V | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1309355498, COSV99873330; called by muse, mutect2, varscan2
- FAM20A | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as rs147626178; called by muse, mutect2, varscan2
- FAM76B | c.206C>T p.T69M | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs565105324, COSV57688045; called by muse, mutect2, varscan2
- FANCD2 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 54/146 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746722465, COSV55032032; called by muse, mutect2, varscan2
- FBN1 | c.3487G>A p.A1163T | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1481457003, COSV100354994; called by muse, mutect2, varscan2
- FBN3 | c.2758C>T p.R920* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as rs759862434, COSV54458104; called by muse, mutect2, varscan2
- FBXL12 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.619); catalogued as rs535415557, COSV99927956; called by muse, varscan2
- FCAR | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.442); catalogued as rs373544789; called by muse, mutect2, varscan2
- FER | c.1447C>T p.R483* | Nonsense Mutation (SNP) | VAF 16/40 reads (40%) | catalogued as rs1352925289, COSV99812314, COSV99812734; called by muse, mutect2, varscan2
- FERD3L | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51763265; called by muse, mutect2, varscan2
- FFAR3 | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs760108323, COSV100588198; called by muse, mutect2, varscan2
- FGF17 | c.14G>A p.R5H | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs373461524, COSV63925383; called by muse, mutect2, varscan2
- FGGY | c.1186C>T p.R396W | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753670605, COSV58049403; called by muse, mutect2, varscan2
- FKBP9 | c.1666G>A p.E556K | Missense Mutation (SNP) | VAF 73/213 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.374); catalogued as rs530788472, COSV99639683; called by muse, mutect2, varscan2
- FLNA | c.4898G>A p.R1633H | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.871); catalogued as rs782500981, COSV61054681; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLNB | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs574643677, COSV99913103; called by muse, mutect2, varscan2
- FLNB | c.2209G>A p.G737R | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs745714160, COSV99913111; called by muse, mutect2, varscan2
- FOXN3 | c.145C>T p.R49* | Nonsense Mutation (SNP) | VAF 13/41 reads (32%) | catalogued as rs917056988, COSV99726418; called by muse, mutect2, varscan2
- FRA10AC1 | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 19/69 reads (28%) | catalogued as rs555127846, COSV100784704; called by muse, mutect2, varscan2
- FRAS1 | c.7912G>A p.V2638M | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs200710024; called by muse, mutect2, varscan2
- FRS3 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as rs758259654, COSV99442827; called by muse, mutect2, varscan2
- FUT2 | c.992C>T p.T331I | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs371234860, COSV101218084; called by muse, mutect2
- FYB2 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 66/195 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs755007742, COSV58587299; called by muse, mutect2, varscan2
- GATAD2A | c.1823C>T p.S608L | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as rs371061090; called by muse, mutect2, varscan2
- GBA2 | c.2368G>A p.V790I | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200544152, COSV100803384; called by muse, mutect2, varscan2
- GC | c.934A>G p.T312A | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs1390284665, COSV99909724; called by muse, mutect2, varscan2
- GFPT2 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780878334, COSV53814383; called by muse, varscan2
- GFRA1 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1378070060, COSV62606471; called by muse, mutect2, varscan2
- GIGYF2 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 63/166 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs755816310, COSV65254649; called by muse, mutect2, varscan2
- GLDC | c.1366C>T p.R456W | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs773119895, COSV100394085; called by muse, mutect2, varscan2
- GNAZ | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as COSV99320733; called by muse, mutect2, varscan2
- GOLPH3 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 61/129 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV54061097; called by muse, mutect2, varscan2
- GPATCH2L | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as rs1341319109, COSV55048302; called by muse, mutect2, varscan2
- GPR135 | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.116); catalogued as COSV67749448; called by muse, mutect2, varscan2
- GPR176 | c.574T>C p.C192R | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100137192; called by muse, mutect2, varscan2
- GPX4 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.609); catalogued as COSV62318611; called by muse, mutect2, varscan2
- GRAP | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs745455096, COSV99408187; called by muse, varscan2
- GREB1 | c.406G>A p.V136I | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as rs775697568, COSV52186244; called by muse, mutect2, varscan2
- GREM2 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.063); catalogued as COSV58947365; called by muse, mutect2, varscan2
- GRINA | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.327); catalogued as rs200050797, COSV100507299; called by muse, mutect2, varscan2
- GRM4 | c.1933G>A p.A645T | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.355); catalogued as rs774668792, COSV65215500; called by muse, mutect2, varscan2
- GRPEL2 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs141968352; called by muse, mutect2, varscan2
- GTF2H4 | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs767371516, COSV52559090; called by muse, mutect2, varscan2
- GUCY1A1 | c.769G>A p.V257I | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs372152908; called by muse, mutect2, varscan2
- GYG1 | c.832T>G p.S278A | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV99936832; called by muse, mutect2, varscan2
- HADHB | c.902G>A p.G301D | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM058348, COSV100501997; called by muse, mutect2, varscan2
- HAO1 | c.832A>T p.I278F | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV101113206; called by muse, mutect2, varscan2
- HCCS | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs761222718, COSV100335678; called by muse, mutect2, varscan2
- HECTD4 | c.8069G>A p.R2690H | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs1422284330, COSV66393273; called by muse, mutect2, varscan2
- HECTD4 | c.7458C>T p.P2486= | Splice Region (SNP) | VAF 17/32 reads (53%) | catalogued as rs371700588, COSV101107466; called by muse, mutect2, varscan2
- HERC2 | c.6121G>A p.G2041S | Missense Mutation (SNP) | VAF 29/38 reads (76%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs559923953, COSV99873581, COSV99877107; called by muse, mutect2, varscan2
- HIF1AN | c.385G>A p.V129I | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs146360800, COSV54499800, COSV54500155; called by muse, mutect2, varscan2
- HIPK4 | c.478G>A p.G160R | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52525404; called by muse, mutect2
- HIVEP3 | c.1243G>A p.A415T | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as rs749306265, COSV99912536; called by muse, mutect2, varscan2
- HIVEP3 | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs377429669, COSV56017131; called by muse, mutect2, varscan2
- HS3ST1 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779505564, COSV99136701; called by muse, varscan2
- HSPA13 | c.661G>A p.V221I | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.87); PolyPhen probably damaging (0.997); catalogued as COSV99580026; called by muse, mutect2, varscan2
- HSPA5 | c.1672C>T p.R558C | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.082); catalogued as rs762500054, COSV99413399; called by muse, mutect2, varscan2
- HTR1D | c.557C>T p.S186L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs753101503, COSV100024861; called by muse, mutect2, varscan2
- HTR4 | c.725C>T p.S242L | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as rs201078356, COSV58797529; called by muse, mutect2, varscan2
- HUWE1 | c.7963T>C p.C2655R | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV99472230; called by muse, mutect2, varscan2
- HUWE1 | c.3412A>G p.T1138A | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.535); catalogued as COSV99472234; called by muse, mutect2, varscan2
- ICMT | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1163453055, COSV59474713; called by muse, mutect2, varscan2
- IFI27L1 | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.289); catalogued as rs200682471; called by muse, mutect2, varscan2
- IFT172 | c.570+1G>A p.X190_splice | Splice Site (SNP) | VAF 8/32 reads (25%) | catalogued as COSV99562470; called by muse, mutect2
- IGF2BP1 | c.818C>T p.T273M | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as rs747081335, COSV99288633; called by muse, varscan2
- IGF2R | c.4874T>C p.M1625T | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as rs1023651528, COSV100807337; called by muse, mutect2, varscan2
- IGHV3-15 | c.355A>G p.T119A | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.093); catalogued as rs781969714; called by muse, mutect2, varscan2
- IGSF1 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.081); catalogued as rs1215064968, COSV63836099; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1940C>T p.T647M | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.235); catalogued as rs367966545, COSV100780682, COSV61160689; called by muse, mutect2, varscan2
- IL20RB | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.047); catalogued as COSV59047997; called by muse, mutect2, varscan2
- IL22RA2 | c.125A>G p.H42R | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV99760668; called by muse, mutect2, varscan2
- ING3 | c.861G>T p.Q287H | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.948); catalogued as COSV100253285; called by muse, mutect2, varscan2
- INPP4B | c.2605A>G p.K869E | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as COSV104369588, COSV99524548; called by muse, mutect2, varscan2
- INTS3 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 59/163 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59679254; called by muse, mutect2, varscan2
- IPO5 | c.2093A>C p.E698A | Missense Mutation (SNP) | VAF 49/81 reads (60%) | SIFT tolerated (0.21); PolyPhen benign (0.044); catalogued as COSV99847279, COSV99847473; called by muse, mutect2, varscan2
- IQGAP1 | c.2822del p.N941Ifs*8 | Frame Shift Del (DEL) | VAF 16/26 reads (62%) | catalogued as rs771739474; called by mutect2, varscan2
- IQGAP3 | c.3305C>T p.P1102L | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs780842801, COSV100752144; called by muse, mutect2, varscan2
- IQSEC1 | c.2572C>T p.R858W | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1232118149, COSV56226447; called by muse, mutect2, varscan2
- IRAG1 | c.2057C>T p.T686M | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs368228015; called by muse, mutect2, varscan2
- ITGA2 | c.646T>C p.Y216H | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56866566; called by muse, mutect2, varscan2
- ITGAV | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs894915282, COSV53720441; called by muse, mutect2, varscan2
- ITPR1 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs745432988, COSV100229949, COSV56970851; called by muse, mutect2, varscan2
- ITPRID2 | c.2644G>A p.A882T | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs765566356, COSV57475532; called by muse, mutect2, varscan2
- JAKMIP2 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.164); catalogued as rs756609174, COSV54617617; called by muse, mutect2, varscan2
- JMJD4 | c.459A>C p.K153N | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV100248135; called by muse, mutect2, varscan2
- JMJD8 | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 10/11 reads (91%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.847); catalogued as rs368155773; called by muse, varscan2
- KASH5 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.475); catalogued as rs770218186, COSV101483441; called by muse, mutect2, varscan2
- KBTBD3 | c.1049G>A p.C350Y | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV101595689; called by muse, mutect2, varscan2
- KCNA3 | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0.069); catalogued as rs755732546, COSV63901132; called by muse, mutect2, varscan2
- KCNH3 | c.2072G>A p.R691H | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs763321479, COSV57793215; called by muse, mutect2, varscan2
- KCNJ4 | c.34G>A p.V12M | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as rs1241626917, COSV100341188; called by muse, mutect2, varscan2
- KCNS3 | c.623C>T p.S208L | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs368555119; called by muse, mutect2, varscan2
- KIAA0100 | c.5117G>A p.R1706H | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101197304; called by muse, mutect2, varscan2
- KIAA0100 | c.4483C>T p.P1495S | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.71); PolyPhen benign (0.027); catalogued as COSV101197305; called by muse, mutect2, varscan2
- KIAA0586 | c.4343G>A p.R1448H (on ENST00000619416 / NM_001244190.2; = p.R1387H on NM_014749.5) | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV54185081; called by muse, mutect2, varscan2
- KIAA1549L | c.5084C>T p.T1695M (on ENST00000321505; = p.T1992M on NM_012194.3) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as rs368033259; called by muse, mutect2, varscan2
- KIF13A | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); catalogued as rs1038727795, COSV52453880; called by muse, mutect2, varscan2
- KIF16B | c.1205T>C p.L402S | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.634); catalogued as COSV100734263; called by muse, mutect2, varscan2
- KIF17 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1260237300, COSV56120132; called by muse, mutect2, varscan2
- KIF1A | c.4586T>C p.L1529P (on ENST00000320389 / NM_001379639.1; = p.L1521P on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.394); catalogued as rs1295184157, COSV100240892; called by muse, mutect2, varscan2
- KIF2A | c.672A>G p.I224M | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101136456; called by muse, mutect2, varscan2
- KIF5A | c.1403G>A p.R468Q | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs774379377, COSV99672946; called by muse, mutect2, varscan2
- KLHL1 | c.1093G>T p.D365Y | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100917230; called by muse, mutect2, varscan2
- KLHL10 | c.1423G>A p.V475M | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs782736217, COSV99509508; called by muse, mutect2, varscan2
- KLHL20 | c.350G>T p.R117M | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as COSV99268375; called by muse, varscan2
- KLHL20 | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.36); catalogued as COSV99268377; called by muse, varscan2
- KLHL5 | c.1351C>T p.R451* | Nonsense Mutation (SNP) | VAF 39/86 reads (45%) | catalogued as rs746202280, COSV99785300; called by muse, mutect2, varscan2
- KLHL6 | c.605T>C p.V202A | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.85); PolyPhen benign (0.005); catalogued as COSV58069858; called by muse, mutect2, varscan2
- KMT2D | c.1994C>T p.P665L | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs780891095, COSV56450900, COSV56460217; ClinVar: likely benign; called by muse, varscan2
- KNDC1 | c.3104G>A p.R1035Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as rs113746324; called by muse, varscan2
- KRTAP13-4 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1051757052, COSV61878955; called by muse, mutect2, varscan2
- KSR2 | c.1271C>T p.T424M | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.475); catalogued as rs552480492, COSV56675883; called by muse, mutect2, varscan2
- LAMA2 | c.6883C>T p.R2295C | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773802779, COSV101370304; called by muse, mutect2, varscan2
- LAMA4 | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377633183, COSV57894262; called by muse, varscan2
- LAMC2 | c.2305G>A p.V769I | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0.041); catalogued as rs768252173, COSV99917435; called by muse, mutect2, varscan2
- LEMD2 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99540662; called by muse, mutect2, varscan2
- LETM2 | c.794G>A p.G265D (on ENST00000379957 / NM_001286819.2; = p.G170D on NM_144652.3) | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99907404; called by muse, mutect2, varscan2
- LNX1 | c.1170G>T p.E390D (on ENST00000263925 / NM_001126328.3; = p.E294D on NM_032622.2) | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.72); PolyPhen benign (0.039); catalogued as COSV99819962; called by muse, mutect2, varscan2
- LRCH3 | c.1237C>T p.R413* | Nonsense Mutation (SNP) | VAF 34/74 reads (46%) | catalogued as rs754999037, COSV100605081; called by muse, mutect2, varscan2
- LRP4 | c.2993G>A p.R998H | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs746964729, COSV101066492; called by muse, varscan2
- LRRC37A2 | c.3077G>A p.C1026Y | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV100238738; called by mutect2, varscan2
- LRRC37A2 | c.4067A>G p.Q1356R | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100238739; called by muse, mutect2, varscan2
- LRRC45 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.566); catalogued as rs764472284, COSV60712761; called by muse, mutect2, varscan2
- LRRC8E | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs146121701; called by muse, mutect2, varscan2
- LRRK2 | c.4429C>T p.R1477* | Nonsense Mutation (SNP) | VAF 29/67 reads (43%) | catalogued as rs1010617973, COSV100110135; called by muse, mutect2, varscan2
- LTBP1 | c.4768C>T p.R1590W (on ENST00000404816 / NM_206943.4; = p.R1264W on NM_000627.4) | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.724); catalogued as rs370970352; called by muse, mutect2, varscan2
- LUZP1 | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs370488038; called by muse, mutect2, varscan2
- LYST | c.1637G>A p.R546Q | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs751609899, COSV101089667, COSV67710168; called by muse, mutect2, varscan2
- MACROH2A1 | c.514G>A p.D172N (on ENST00000510038; = p.D171N on NM_004893.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.63); PolyPhen benign (0.151); catalogued as rs761273750, COSV100427635; called by muse, mutect2, varscan2
- MAD1L1 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs1270834962, COSV56236783; called by muse, mutect2, varscan2
- MAGEA12 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as rs1556833497, COSV63294552, COSV63294755; called by muse, mutect2, varscan2
- MAGEB6 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.898); catalogued as rs776261244, COSV100983726, COSV66872916; called by muse, mutect2, varscan2
- MAGEC1 | c.1642T>C p.F548L | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.014); catalogued as COSV53570972, COSV99595668; called by muse, mutect2, varscan2
- MAGEC1 | c.2450T>C p.F817S | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.235); catalogued as COSV99595670; called by muse, mutect2, varscan2
- MAP3K1 | c.3884T>A p.I1295K | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101266741; called by muse, mutect2, varscan2
- MAPK8IP3 | c.3274C>T p.R1092W | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1306450018, COSV51599872; called by muse, mutect2, varscan2
- MASP2 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated (0.23); PolyPhen benign (0.129); catalogued as rs78019538; called by muse, mutect2, varscan2
- MAST3 | c.1241T>C p.V414A | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.19); catalogued as COSV99445228; called by muse, mutect2, varscan2
- MATK | c.302C>T p.A101V (on ENST00000310132 / NM_139355.3; = p.A102V on NM_002378.4) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.373); catalogued as COSV100036063; called by muse, mutect2, varscan2
- MATN2 | c.1672C>A p.R558S | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.049); catalogued as COSV99646274; called by muse, mutect2, varscan2
- MAU2 | c.1268C>T p.A423V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.81); catalogued as COSV53237011; called by mutect2, varscan2
- MCM10 | c.1703G>A p.R568Q (on ENST00000484800 / NM_182751.3; = p.R567Q on NM_018518.5) | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373990822, COSV66336024; called by muse, mutect2, varscan2
- MCOLN1 | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.58); PolyPhen benign (0.009); catalogued as rs147718736; called by muse, varscan2
- MED12L | c.3020G>A p.R1007H | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56387917; called by muse, mutect2, varscan2
- MED12L | c.4880T>C p.L1627S | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56380711; called by muse, mutect2, varscan2
- MED24 | c.2695C>T p.R899* | Nonsense Mutation (SNP) | VAF 18/44 reads (41%) | catalogued as rs1168375950, COSV99842430; called by muse, mutect2, varscan2
- MED9 | c.350A>T p.Q117L | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs137951481; called by muse, varscan2
- MEGF8 | c.4490G>A p.S1497N (on ENST00000251268 / NM_001271938.2; = p.S1430N on NM_001410.3) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.306); catalogued as rs1037700454, COSV99236127; called by muse, mutect2, varscan2
- MFSD14A | c.988T>G p.F330V | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.302); catalogued as COSV64514502; called by muse, mutect2, varscan2
- MGA | c.4148G>A p.R1383Q | Missense Mutation (SNP) | VAF 45/69 reads (65%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs761482641, COSV54961299, COSV99579909; called by muse, mutect2, varscan2
- MICAL3 | c.5162C>T p.P1721L | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs756390963, COSV71588635; called by muse, mutect2, varscan2
- MLLT10 | c.2398G>A p.A800T (on ENST00000307729 / NM_001195626.3; = p.A816T on NM_004641.3) | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100308081; called by muse, mutect2, varscan2
- MMS19 | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1466060056, COSV100512855; called by muse, mutect2, varscan2
- MMS22L | c.2455C>T p.R819C | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs751871617, COSV51516916; called by muse, mutect2, varscan2
- MPRIP | c.1748G>A p.R583Q | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as rs750857702, COSV57927868; called by muse, mutect2, varscan2
- MRAP2 | c.169G>A p.V57M | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs749880950, COSV100004790; called by muse, mutect2, varscan2
- MROH8 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as rs568788866, COSV99457237; called by muse, mutect2, varscan2
- MS4A8 | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.253); catalogued as rs758725009, COSV55753158; called by muse, mutect2, varscan2
- MTMR3 | c.2731A>G p.T911A | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as COSV100070804; called by muse, mutect2, varscan2
- MUC16 | c.39169G>A p.G13057S | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.928); catalogued as rs534033129, COSV101199876; called by muse, mutect2, varscan2
- MXRA5 | c.7014A>T p.R2338S | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV99476895; called by muse, varscan2
- MXRA5 | c.6937G>A p.E2313K | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.971); catalogued as rs1174165543, COSV54223661; called by muse, varscan2
- MXRA5 | c.5788G>A p.A1930T | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs193920874, COSV54230682; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MXRA5 | c.2044C>T p.R682C | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as rs768847893, COSV54231645; called by muse, mutect2, varscan2
- MYH3 | c.3985G>A p.A1329T | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.127); catalogued as rs923371415, COSV99878201; called by muse, mutect2
- MYO1A | c.1864C>T p.R622W | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753058903, COSV55655200; called by muse, mutect2
- MYRIP | c.1670C>T p.S557L | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.66); PolyPhen benign (0.005); catalogued as rs201954262; called by muse, mutect2, varscan2
- NALCN | c.148G>A p.V50I | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.31); catalogued as rs765386270, COSV99215057; called by muse, mutect2, varscan2
- NAPEPLD | c.764G>A p.C255Y | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV100439848; called by muse, mutect2, varscan2
- NAV2 | c.5711T>C p.V1904A (on ENST00000396087 / NM_001244963.2; = p.V1845A on NM_145117.5) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100216838; called by muse, mutect2, varscan2
- NBAS | c.1564C>T p.R522C | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs187987936; called by muse, mutect2, varscan2
- NBEAL2 | c.1960G>T p.V654L | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99435863; called by muse, mutect2, varscan2
- NCAPD3 | c.2872C>T p.R958C | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1271577879, COSV73244823, COSV73244848; called by muse, mutect2
- NCAPG2 | c.2932C>T p.R978W | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as rs746675602, COSV99316930; called by muse, mutect2, varscan2
- NCOA3 | c.478A>G p.I160V | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.705); catalogued as rs1300949817, COSV100507550; called by muse, mutect2, varscan2
- NDRG1 | c.271G>A p.V91I | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.164); catalogued as rs781433633, COSV100106040; called by muse, mutect2, varscan2
- NEB | c.14326C>T p.R4776C | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765181095, COSV51469236; called by muse, mutect2, varscan2
- NECAB2 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs750013163, COSV100533927, COSV100533951; called by muse, mutect2, varscan2
- NECTIN1 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs185201594, COSV99872123; called by muse, mutect2, varscan2
- NEDD9 | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV101053398; called by muse, mutect2, varscan2
- NEK4 | c.1973G>A p.R658Q | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs759932343, COSV51782760; called by muse, mutect2, varscan2
- NEK4 | c.1859G>A p.R620Q | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs769037062, COSV51782081; called by muse, mutect2, varscan2
- NF1 | c.8446G>A p.G2816R (on ENST00000358273 / NM_001042492.3; = p.G2795R on NM_000267.3) | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs778233452, COSV100647000; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NFATC3 | c.2504A>G p.D835G | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.129); catalogued as COSV100285171; called by muse, mutect2, varscan2
- NIPBL | c.4607G>A p.R1536Q | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV56958690; called by muse, mutect2, varscan2
- NLRP2 | c.1891C>T p.H631Y | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV99672259; called by muse, mutect2, varscan2
- NNT | c.1748A>T p.D583V | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV99238908; called by muse, mutect2, varscan2
- NOMO1 | c.1895-2A>G p.X632_splice | Splice Site (SNP) | VAF 21/170 reads (12%) | catalogued as COSV99814520; called by muse, mutect2, varscan2
- NOP2 | c.958C>T p.R320* (on ENST00000322166 / NM_001258308.2; = p.R316* on NM_006170.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 17/38 reads (45%) | catalogued as COSV59112353; called by muse, mutect2, varscan2
- NOTCH4 | c.1046dup p.T350Hfs*4 | Frame Shift Ins (INS) | VAF 8/18 reads (44%) | catalogued as rs766348245; called by mutect2, varscan2
- NPC1 | c.2218T>C p.F740L | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV99341301; called by muse, mutect2, varscan2
- NPHS1 | c.3275G>A p.R1092H | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs144203682; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NR2C1 | c.679A>G p.S227G | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs765545391, COSV100280472; called by muse, mutect2, varscan2
- NRF1 | c.1016C>T p.T339I | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as COSV99781774; called by muse, mutect2, varscan2
- NRXN3 | c.2194G>A p.D732N (on ENST00000335750 / NM_001330195.2; = p.D359N on NM_004796.6) | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1225607419, COSV59726855, COSV59777471; called by muse, mutect2, varscan2
- NT5DC1 | c.752A>C p.K251T | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100126653; called by muse, mutect2, varscan2
- NTSR1 | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.773); catalogued as rs750726392, COSV65138957; called by muse, mutect2, varscan2
- NUMB | c.1937C>T p.T646M (on ENST00000355058; = p.T635M on NM_003744.5) | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs1473856864, COSV99389618; called by muse, mutect2, varscan2
- NUP133 | c.1976G>A p.R659Q | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.097); catalogued as COSV99772905; called by muse, mutect2, varscan2
- NUP205 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs369458508; called by muse, mutect2, varscan2
- NXT1 | c.269C>T p.T90M | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs780312087, COSV99656348; called by muse, mutect2, varscan2
- NYNRIN | c.3554C>A p.P1185H | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs574649411, COSV101230588, COSV66842755; called by muse, mutect2, varscan2
- OAS1 | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as rs754280709, COSV99177152; called by muse, mutect2, varscan2
- OAS3 | c.2441G>A p.R814H | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.916); catalogued as rs540763104, COSV99966267; called by muse, varscan2
- OBSCN | c.15734G>A p.R5245Q | Missense Mutation (SNP) | VAF 22/29 reads (76%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as rs780627727, COSV52760892; called by muse, varscan2
- OGA | c.2448G>T p.E816D | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100761809; called by muse, mutect2, varscan2
- OGFOD2 | c.544G>A p.E182K (on ENST00000228922 / NM_001304833.1; = p.E122K on NM_024623.3) | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs769287485, COSV99758883; called by muse, varscan2
- OGT | c.1669C>T p.R557C | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs759414360, COSV65480725; called by muse, mutect2, varscan2
- OLFML2A | c.1480C>T p.R494C | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775121644, COSV56583722; called by muse, mutect2, varscan2
- OPN1SW | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs149847165, COSV50821566; called by muse, varscan2
- OPN1SW | c.307G>A p.G103S | Missense Mutation (SNP) | VAF 50/90 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201892828, COSV99975667; called by muse, varscan2
- OR10J1 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs771261208, COSV101419876; called by muse, mutect2, varscan2
- OR13F1 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs191015152, COSV58251628; called by muse, varscan2
- OR13H1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs1360450855, COSV100088251; called by muse, mutect2, varscan2
- OR1J1 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs1265486163, COSV52237174; called by muse, mutect2, varscan2
- OR2M7 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 62/177 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as rs746504653, COSV58739412; called by muse, mutect2, varscan2
- OR56B1 | c.571C>A p.L191I | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.962); catalogued as COSV100402619; called by muse, mutect2, varscan2
- ORAI3 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs923312049, COSV99352934; called by muse, mutect2, varscan2
- OTOGL | c.6953G>A p.R2318H (on ENST00000547103; = p.R2309H on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756670112, COSV100087245; called by muse, mutect2, varscan2
- OTX2 | c.253T>C p.W85R (on ENST00000408990 / NM_172337.3; = p.W93R on NM_021728.4) | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100257934; called by muse, mutect2, varscan2
- OVGP1 | c.1100G>A p.C367Y | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as rs140775603; called by muse, mutect2, varscan2
- OVOL1 | c.427G>A p.V143I | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.061); catalogued as rs577150616, COSV60119592; called by muse, mutect2, varscan2
- PABPC4 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV100865452; called by muse, mutect2, varscan2
- PACSIN2 | c.1433C>T p.P478L | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1354343021, COSV99606213; called by muse, mutect2, varscan2
- PADI3 | c.199C>T p.R67W | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as rs111914086; called by muse, mutect2, varscan2
- PAGE5 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 75/193 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.339); catalogued as COSV99215760; called by muse, mutect2, varscan2
- PALLD | c.2935C>T p.R979C (on ENST00000505667 / NM_001166108.2; = p.R962C on NM_016081.4) | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367575623; called by muse, mutect2, varscan2
- PARL | c.1037T>C p.V346A | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100226200; called by muse, mutect2, varscan2
- PARVG | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100796077; called by muse, mutect2
- PBX3 | c.935C>T p.A312V | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as COSV60730105; called by muse, mutect2, varscan2
- PCDH1 | c.2624G>A p.R875H | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs568532537, COSV99745549; called by muse, mutect2, varscan2
- PCDH15 | c.4911G>T p.E1637D | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.469); catalogued as COSV100220613; called by muse, mutect2, varscan2
- PCDHA9 | c.1663G>A p.V555M | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs1189332521, COSV100969500; called by muse, mutect2, varscan2
- PCDHB5 | c.2249A>G p.Y750C | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.167); catalogued as COSV99167896; called by muse, mutect2, varscan2
- PCDHGA10 | c.1880C>T p.T627M | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as rs767474996, COSV53918569; called by muse, mutect2, varscan2
- PCDHGA2 | c.763A>G p.T255A | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as rs1448912033, COSV99537873; called by muse, mutect2, varscan2
- PCDHGA3 | c.1636G>A p.V546M | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.378); catalogued as COSV53938956; called by muse, varscan2
- PCDHGA3 | c.1675G>A p.A559T | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.003); catalogued as COSV53904010; called by muse, varscan2
- PCM1 | c.2563G>T p.G855C | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100279076; called by muse, mutect2, varscan2
- PCOLCE2 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200433586, COSV56001507; called by muse, mutect2, varscan2
- PCYOX1 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs768225174, COSV100037197; called by muse, mutect2, varscan2
- PCYT1B | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs771505211, COSV100996865; called by muse, mutect2, varscan2
- PDCD1 | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372765600; called by muse, mutect2, varscan2
- PDCD11 | c.4532C>T p.A1511V | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100874325; called by muse, mutect2, varscan2
- PDE9A | c.842A>G p.D281G | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as COSV99371522; called by muse, mutect2, varscan2
- PDGFD | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.27); catalogued as rs1474231473, COSV100159118, COSV100160890; called by muse, mutect2, varscan2
- PDHB | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs868788199, CM0910759, COSV57056925, COSV57057096; called by muse, mutect2, varscan2
- PDIA4 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as rs757583934, COSV99618511; called by muse, mutect2, varscan2
- PDXDC1 | c.1096C>T p.R366W | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.614); catalogued as rs541688833; called by muse, mutect2
- PEX1 | c.2311C>T p.H771Y | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99952096; called by muse, mutect2, varscan2
- PFN4 | c.136C>T p.R46* | Nonsense Mutation (SNP) | VAF 32/71 reads (45%) | catalogued as rs376361343, COSV100500390; called by muse, mutect2, varscan2
- PGAP2 | c.466C>T p.H156Y (on ENST00000463452 / NM_001346398.2; = p.H217Y on NM_014489.4) | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.68); PolyPhen benign (0.021); catalogued as COSV99544276; called by muse, mutect2, varscan2
- PGBD1 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs201136697; called by muse, mutect2, varscan2
- PGBD5 | c.1060C>T p.Q354* (on ENST00000525115; = p.Q423* on NM_001258311.2) | Nonsense Mutation (SNP) | VAF 11/21 reads (52%) | catalogued as COSV100358578; called by muse, mutect2, varscan2
- PHB | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.07); PolyPhen benign (0.127); catalogued as rs1277922087, COSV100303164; called by muse, mutect2, varscan2
- PHF21A | c.1879G>A p.G627S (on ENST00000418153 / NM_001101802.3; = p.G581S on NM_016621.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.04); catalogued as rs376981110; called by muse, mutect2, varscan2
- PHIP | c.2113G>A p.A705T | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as rs1044058522, COSV51502524; called by muse, mutect2, varscan2
- PHKB | c.3043G>A p.E1015K | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1394450119, COSV100066988; called by muse, mutect2, varscan2
- PIK3C2A | c.1618C>T p.P540S | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.782); catalogued as COSV99790714; called by muse, mutect2, varscan2
- PIK3R5 | c.1619G>A p.R540Q | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs751766838, COSV99353302; called by muse, varscan2
- PIN4 | c.185C>T p.A62V (on ENST00000664196; = p.A37V on NM_006223.4) | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.602); catalogued as COSV99512486; called by muse, mutect2, varscan2
- PIP5K1A | c.1166G>A p.R389Q (on ENST00000368888 / NM_001135638.2; = p.R376Q on NM_003557.3) | Missense Mutation (SNP) | VAF 76/152 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs748351425, COSV100576612; called by muse, mutect2, varscan2
- PITPNM1 | c.3727G>A p.E1243K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as rs200206163, COSV54162094; called by muse, varscan2
- PKIG | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.961); catalogued as COSV63068682; called by muse, mutect2, varscan2
- PKN1 | c.2197G>A p.E733K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as COSV99466436; called by muse, mutect2, varscan2
- PKP4 | c.2674G>A p.V892M | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs755733460, COSV61579869; called by muse, mutect2, varscan2
- PLCXD3 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs182360912, COSV60606280; called by muse, mutect2, varscan2
- PLEKHA8 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 61/156 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99321756; called by muse, mutect2, varscan2
- PLEKHG6 | c.1660G>A p.A554T | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs776513105, COSV99164199; called by muse, mutect2
- PLEKHS1 | c.92C>T p.S31F (on ENST00000369310 / NM_182601.1; = p.S37F on NM_024889.5) | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100732813; called by muse, mutect2, varscan2
- PLK1 | c.1321C>T p.R441C | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1353944469, COSV55623295; called by muse, mutect2, varscan2
- PLOD3 | c.1492C>T p.R498* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as rs762008131, COSV56181238; called by muse, mutect2, varscan2
- PLSCR5 | c.114G>T p.W38C | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.174); catalogued as COSV101494488; called by muse, mutect2, varscan2
- PLXNB2 | c.3737G>A p.R1246Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100833832; called by muse, mutect2, varscan2
- PLXNB3 | c.5359G>A p.A1787T | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1003955955, COSV100737402; called by muse, mutect2, varscan2
- PNLIPRP2 | c.1205C>T p.T402M (on ENST00000611850; = p.T403M on NM_005396.5) | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs199740944; called by muse, mutect2, varscan2
- PNMA3 | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as rs782049640, COSV64722539; called by muse, mutect2, varscan2
- PNP | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1181802215, COSV100828963; called by muse, mutect2, varscan2
- PNPT1 | c.16T>A p.Y6N | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as rs919792111, COSV99569985, COSV99570091, COSV99570345; called by mutect2, varscan2
- POLE | c.2341G>T p.A781S | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.023); catalogued as COSV100266588; called by muse, mutect2, varscan2
- POLE | c.2091dup p.F699Vfs*11 | Frame Shift Ins (INS) | VAF 16/34 reads (47%) | catalogued as rs752846614; ClinVar: uncertain significance; called by mutect2, varscan2
- POLQ | c.3148C>T p.R1050* | Nonsense Mutation (SNP) | VAF 25/67 reads (37%) | catalogued as rs747386606, COSV51759948; called by muse, mutect2, varscan2
- PPARD | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.257); catalogued as COSV100283080; called by muse, mutect2, varscan2
- PPP1R15A | c.1936del p.T646Pfs*4 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | catalogued as COSV99565755; called by mutect2, varscan2
- PPP2R2A | c.305T>C p.L102S | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100277178; called by muse, mutect2, varscan2
- PRDM11 | c.767G>A p.R256Q (on ENST00000530656 / NM_001359633.1; = p.R222Q on NM_001256695.1) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.873); catalogued as rs984566309, COSV99770699; called by muse, mutect2, varscan2
- PRDM16 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as rs779535977, COSV54604583, COSV54608936; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRKRA | c.833C>T p.T278I | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100359584; called by muse, mutect2, varscan2
- PRL | c.671A>G p.N224S | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs1277036674, COSV100123022; called by muse, mutect2, varscan2
- PROS1 | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as rs772677117, COSV67776359; called by muse, mutect2, varscan2
- PRRC2A | c.4555G>A p.E1519K | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs916204518, COSV101051180; called by muse, mutect2, varscan2
- PRRC2B | c.5543C>A p.P1848H | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100260987; called by muse, mutect2, varscan2
- PRRT2 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs754897123, COSV54881782; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRSS36 | c.1522-2A>G p.X508_splice | Splice Site (SNP) | VAF 12/23 reads (52%) | catalogued as COSV99191267; called by muse, mutect2, varscan2
- PRUNE2 | c.3488C>T p.P1163L | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs145706309; called by muse, mutect2, varscan2
- PSD4 | c.2624+1G>A p.X875_splice | Splice Site (SNP) | VAF 11/21 reads (52%) | catalogued as COSV55524608; called by muse, mutect2, varscan2
- PSG7 | c.937C>T p.R313W | Missense Mutation (SNP) | VAF 137/346 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.039); catalogued as rs376480204, COSV68446285; called by muse, mutect2, varscan2
- PSG8 | c.658C>T p.R220W | Missense Mutation (SNP) | VAF 100/249 reads (40%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.893); catalogued as rs141410321; called by muse, mutect2, varscan2
- PSMB11 | c.682G>A p.V228M | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.986); catalogued as rs371415547; called by muse, varscan2
- PSME4 | c.827T>C p.V276A | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV101122482; called by muse, mutect2, varscan2
- PTCH2 | c.2678C>T p.T893M | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.195); catalogued as rs199596045; ClinVar: uncertain significance; called by muse, varscan2
- PTCH2 | c.703C>T p.R235W | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs200366479; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTK2 | c.2522G>A p.R841Q | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs767144547, COSV61795662; called by muse, mutect2, varscan2
- PTK2 | c.2264C>T p.A755V | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs1403693308, COSV100570151; called by muse, mutect2, varscan2
- PTPN13 | c.1382C>T p.P461L | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs375963027; called by muse, mutect2
- PTPRB | c.118G>A p.V40M | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.013); catalogued as rs925084256, COSV99317457; called by muse, mutect2, varscan2
- PTPRF | c.3950G>A p.R1317Q | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as rs777629923, COSV100740646, COSV100740877; called by muse, mutect2, varscan2
- PTPRS | c.3581G>A p.R1194H | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.886); catalogued as rs115469963; called by muse, varscan2
- PTPRZ1 | c.2390C>T p.T797M | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs764900751, COSV66437476; called by muse, mutect2, varscan2
- QSER1 | c.3302G>A p.R1101H (on ENST00000399302; = p.R1230H on NM_001076786.3) | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs769490998, COSV67900643; called by muse, varscan2
- RABEPK | c.472G>A p.G158R | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150980160, COSV99413520; called by muse, mutect2, varscan2
- RABGAP1 | c.2789dup p.N930Kfs*7 | Frame Shift Ins (INS) | VAF 32/106 reads (30%) | catalogued as rs749213218; called by mutect2, varscan2
- RAC1 | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 11/34 reads (32%) | catalogued as COSV100641009; called by muse, mutect2, varscan2
- RAD9A | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as rs377299831; called by muse, varscan2
- RALBP1 | c.1690G>A p.E564K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs753692835, COSV99191920; called by muse, mutect2, varscan2
- RALGAPA2 | c.3680G>A p.R1227Q | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs373227779, COSV52504369; called by muse, mutect2, varscan2
- RASGRP4 | c.1478G>A p.R493Q | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.084); catalogued as rs775615920, COSV99384984; called by muse, mutect2, varscan2
- RBM15B | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as COSV100082127; called by muse, mutect2
- RBM7 | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 63/144 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs771270717, COSV64955532; called by muse, mutect2, varscan2
- RC3H2 | c.2095C>T p.R699C | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs992310336, COSV61800084; called by muse, mutect2, varscan2
- RCE1 | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773493789, COSV58993384; called by muse, varscan2
- RESF1 | c.2371G>A p.V791I | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.447); catalogued as rs763753313, COSV57019973; called by muse, mutect2, varscan2
- RIMBP3 | c.3433A>G p.S1145G | Missense Mutation (SNP) | VAF 38/249 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs768698451; called by muse, mutect2, varscan2
- RIMS2 | c.3146G>A p.R1049H (on ENST00000666250 / NM_001348490.2; = p.R857H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs995050197, COSV51669002; called by muse, mutect2, varscan2
- RNF128 | c.31del p.W11Gfs*4 | Frame Shift Del (DEL) | VAF 23/66 reads (35%) | catalogued as rs757038390; called by mutect2, varscan2
- RNPEP | c.1817C>T p.P606L | Missense Mutation (SNP) | VAF 46/89 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779636715, COSV99821460; called by muse, mutect2, varscan2
- ROGDI | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV100424257; called by muse, varscan2
- RP1L1 | c.1294G>A p.V432I | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs749125819, COSV101223176; called by muse, varscan2
- RPH3A | c.1846G>A p.E616K (on ENST00000389385 / NM_001143854.2; = p.E612K on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1410288764, COSV66989937; called by muse, mutect2, varscan2
- RRBP1 | c.3442A>C p.S1148R (on ENST00000377813 / NM_001365613.2; = p.S715R on NM_004587.3) | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99853999; called by muse, mutect2, varscan2
- RRN3 | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.118); catalogued as rs202026072, COSV99548796; called by muse, mutect2, varscan2
- RRP12 | c.2507G>A p.R836H | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs560486956, CM164973, COSV59669394; called by muse, mutect2, varscan2
- RRP8 | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146302834; called by muse, mutect2, varscan2
- RSF1 | c.3820C>T p.R1274W | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as COSV57845107; called by muse, mutect2, varscan2
- RSKR | c.629C>G p.A210G | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV99972081; called by muse, mutect2, varscan2
- RSRC1 | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.687); catalogued as rs773664146, COSV99906157; called by muse, varscan2
- RTL1 | c.2831C>A p.P944H | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101128276; called by muse, mutect2, varscan2
- RTN4IP1 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as rs760154556, COSV100954180; called by muse, mutect2, varscan2
- RYR3 | c.3440T>C p.V1147A | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101212734; called by muse, mutect2, varscan2
- RYR3 | c.5078C>T p.T1693M | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.511); catalogued as rs370691735; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAG | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.108); catalogued as rs996188359, COSV68590424; called by muse, mutect2, varscan2
- SAMD9L | c.4547del p.N1516Mfs*10 | Frame Shift Del (DEL) | VAF 12/41 reads (29%) | catalogued as COSV59083791; called by mutect2, varscan2
- SAMHD1 | c.1324C>T p.R442* | Nonsense Mutation (SNP) | VAF 45/116 reads (39%) | catalogued as rs369587937, CM093964, COSV53428963; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- SAMM50 | c.544G>A p.G182R | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as rs183923403, COSV100601345; called by muse, mutect2, varscan2
- SARDH | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753922256, COSV53833416; called by muse, mutect2, varscan2
- SCML1 | c.459C>A p.N153K (on ENST00000380041 / NM_001037540.3; = p.N126K on NM_006746.6) | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as COSV101193939; called by muse, mutect2, varscan2
- SCML2 | c.1673C>T p.A558V | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.073); catalogued as COSV99318955; called by muse, mutect2, varscan2
- SCN2A | c.2860G>A p.A954T | Missense Mutation (SNP) | VAF 28/243 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs749485469, COSV99331595; called by muse, mutect2, varscan2
- SCRG1 | c.71A>T p.N24I | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.033); catalogued as COSV99633469; called by muse, mutect2, varscan2
- SCUBE3 | c.1784G>A p.R595H | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.869); catalogued as rs1445958418, COSV99234431; called by muse, mutect2
- SEC14L4 | c.1087C>A p.L363M | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99742770, COSV99742949; called by muse, varscan2
- SEC23A | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs768946218, COSV100305217; called by muse, mutect2, varscan2
- SEC24C | c.1408C>T p.R470C | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100226798; called by muse, mutect2, varscan2
- SELL | c.677C>T p.P226L (on ENST00000650983; = p.P213L on NM_000655.5) | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99357552; called by muse, mutect2, varscan2
- SEMA6C | c.1375C>T p.R459* | Nonsense Mutation (SNP) | VAF 11/35 reads (31%) | catalogued as rs761547481, COSV100501298; called by muse, mutect2
- SEMA7A | c.574C>T p.R192W | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs996482431, COSV99984763; called by muse, mutect2, varscan2
- SERPINA1 | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT tolerated (0.17); PolyPhen benign (0.301); catalogued as rs758820515, COSV100871980, COSV63345335; called by muse, mutect2, varscan2
- SERPINB9 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.036); catalogued as rs202159163, COSV66233937; called by muse, mutect2, varscan2
- SGSM3 | c.1828C>T p.R610C | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755966818, COSV99960406; called by muse, mutect2, varscan2
- SH2B1 | c.1739C>T p.S580L | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs373897209; called by muse, mutect2, varscan2
- SH2D3A | c.559G>C p.A187P | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.069); catalogued as COSV99837966; called by muse, mutect2, varscan2
- SH3BP4 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773922347, COSV100749162; called by muse, varscan2
- SHMT1 | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1016685768, COSV57400881; called by muse, mutect2, varscan2
- SHROOM3 | c.4247C>T p.T1416M | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745954438, COSV99934289; called by muse, varscan2
- SI | c.5110C>A p.R1704= | Splice Region (SNP) | VAF 18/49 reads (37%) | catalogued as COSV100015478, COSV52275176; called by muse, mutect2, varscan2
- SIRT1 | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 60/167 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs1426968560, COSV53019448; called by muse, mutect2, varscan2
- SIRT2 | c.1037G>A p.R346Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs201687831, COSV50877339; called by muse, varscan2
- SLC12A7 | c.1125C>A p.F375L | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV53758279, COSV99369843; called by muse, varscan2
- SLC13A2 | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.573); catalogued as rs782607614, COSV100120313; called by muse, mutect2, varscan2
- SLC13A2 | c.1595A>G p.K532R | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.119); catalogued as COSV100120316; called by muse, mutect2, varscan2
- SLC16A7 | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 66/178 reads (37%) | catalogued as rs755179284, COSV53894970; called by muse, mutect2, varscan2
- SLC1A2 | c.49C>T p.R17* | Nonsense Mutation (SNP) | VAF 10/24 reads (42%) | catalogued as rs921441636, COSV53518336; called by muse, mutect2, varscan2
- SLC22A7 | c.1192C>T p.R398C (on ENST00000372585 / NM_153320.2; = p.R396C on NM_006672.3) | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs891750270, COSV51486402; called by muse, mutect2, varscan2
- SLC25A45 | c.206T>C p.V69A | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.542); catalogued as COSV99587307; called by muse, mutect2, varscan2
- SLC2A8 | c.1211A>G p.H404R | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV100972639; called by muse, mutect2, varscan2
- SLC30A2 | c.692-1G>T p.X231_splice | Splice Site (SNP) | VAF 18/41 reads (44%) | catalogued as COSV100958535; called by muse, mutect2, varscan2
- SLC35E1 | c.856G>A p.V286I | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs1020101948, COSV101290773; called by muse, mutect2, varscan2
- SLC39A2 | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs374140607, COSV100068569; called by muse, mutect2, varscan2
- SLC44A2 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV100213194; called by muse, mutect2, varscan2
- SLC4A4 | c.3164A>G p.Q1055R (on ENST00000264485 / NM_001098484.3; = p.Q1011R on NM_003759.4) | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as COSV99140129; called by muse, mutect2
- SLC4A9 | c.2227C>T p.R743C (on ENST00000507527 / NM_001258428.2; = p.R719C on NM_031467.3) | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs781373088, COSV50183957, COSV99138825; called by muse, mutect2, varscan2
- SLC6A1 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs754493263, COSV99822723; ClinVar: uncertain significance; called by muse, varscan2
- SLC7A8 | c.1253G>A p.R418H | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763323196, COSV100328348; called by muse, mutect2
- SLC9B2 | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.963); catalogued as COSV60020183; called by muse, mutect2, varscan2
- SLCO3A1 | c.1279G>A p.V427I | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as rs776789535, COSV59233121; called by muse, mutect2, varscan2
- SLF1 | c.2291T>C p.L764P | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.424); catalogued as COSV99475899; called by muse, mutect2, varscan2
- SLIRP | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1566822874, COSV99473167; called by muse, mutect2, varscan2
- SLITRK2 | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV100157737; called by muse, mutect2
- SMARCA4 | c.4072A>G p.T1358A | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.074); catalogued as COSV60791846; called by muse, mutect2
- SMC6 | c.1517G>A p.G506D | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100705092; called by muse, mutect2, varscan2
- SMG6 | c.3103G>A p.G1035S | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.29); PolyPhen probably damaging (1); catalogued as rs761840703, COSV99558159; called by muse, mutect2, varscan2
- SMG6 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs745877086, COSV53968233; called by muse, mutect2, varscan2
- SMOC2 | c.730G>A p.G244S (on ENST00000356284 / NM_001166412.2; = p.G255S on NM_022138.3) | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs561879643, COSV62440555; called by muse, mutect2, varscan2
- SMPD4 | c.1505C>T p.A502V (on ENST00000409031 / NM_017951.4; = p.A473V on NM_017751.4) | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs142376219; called by muse, mutect2, varscan2
- SMTNL1 | c.1319A>T p.Q440L (on ENST00000399154; = p.Q477L on NM_001105565.2) | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99761866; called by muse, mutect2, varscan2
- SMURF2 | c.548C>T p.T183M | Missense Mutation (SNP) | VAF 96/237 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs782194804, COSV99300684; called by muse, mutect2, varscan2
- SNAP91 | c.8G>A p.G3D | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748411789, COSV99535205; called by muse, mutect2, varscan2
- SORL1 | c.802C>T p.R268* | Nonsense Mutation (SNP) | VAF 30/93 reads (32%) | catalogued as rs1480691710, CM166726, COSV99493799; called by muse, mutect2, varscan2
- SP4 | c.2005C>T p.R669C | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56026945; called by muse, mutect2, varscan2
- SPAG7 | c.649C>T p.R217W | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs377700806, COSV52780296; called by muse, mutect2, varscan2
- SPAST | c.475G>T p.G159* | Nonsense Mutation (SNP) | VAF 27/68 reads (40%) | catalogued as COSV100188527; called by muse, mutect2, varscan2
- SPTB | c.4343A>G p.E1448G | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV101072124; called by muse, mutect2, varscan2
- SPTY2D1 | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs201551055, COSV100311659; called by muse, varscan2
- SRCAP | c.5111C>T p.T1704M | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs749617098, COSV52679970; called by muse, mutect2, varscan2
- SRGAP1 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1483422708, COSV61894436; called by muse, mutect2, varscan2
- SRGAP2 | c.1210G>A p.E404K (on ENST00000624873 / NM_001170637.4; = p.E405K on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as rs782566986, COSV99832810; called by mutect2, varscan2
- SRPRA | c.1871G>A p.R624H | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs762239532, COSV100141747; called by muse, mutect2, varscan2
- SRSF4 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as rs1229902434, COSV100861394; called by muse, mutect2, varscan2
- SSH3 | c.106C>T p.Q36* | Nonsense Mutation (SNP) | VAF 10/15 reads (67%) | catalogued as COSV100354550; called by muse, mutect2, varscan2
- SSTR2 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); catalogued as rs200265628, COSV59536137; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 36/80 reads (45%) | PolyPhen benign (0.019); catalogued as rs772659772, COSV60347050; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 10/22 reads (45%) | PolyPhen benign (0.006); catalogued as rs781777501, COSV59561894; called by muse, mutect2, varscan2
- STKLD1 | c.74T>C p.M25T | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV100912004; called by muse, mutect2, varscan2
- STPG2 | c.611del p.K204Rfs*6 | Frame Shift Del (DEL) | VAF 32/100 reads (32%) | catalogued as rs778953320; called by mutect2, varscan2
- STRBP | c.865C>T p.R289* | Nonsense Mutation (SNP) | VAF 35/93 reads (38%) | catalogued as COSV62119392; called by muse, mutect2, varscan2
- STUM | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1266620309, COSV64684047, COSV64685057; called by muse, mutect2, varscan2
- STXBP5 | c.2125C>T p.R709C | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs751124208, COSV99470187; called by muse, mutect2, varscan2
- SUDS3 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100820006, COSV64349091; called by muse, mutect2, varscan2
- SUFU | c.1090C>T p.R364W | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1305395503, COSV64015149; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SUPT16H | c.91G>A p.V31I | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs201996123; called by muse, mutect2, varscan2
- SUPT4H1 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as rs770569322, COSV99842765; called by muse, mutect2, varscan2
- SV2C | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 101/283 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs770649936, COSV100456122; called by muse, mutect2, varscan2
- SYNE2 | c.6736G>A p.G2246S | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.14); catalogued as rs774737023, COSV100647610; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- SYNPO2 | c.1961C>T p.P654L | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs1023862013, COSV100205537; called by muse, mutect2, varscan2
- SYNPO2L | c.781C>T p.R261C (on ENST00000394810 / NM_001114133.3; = p.R37C on NM_024875.5) | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750431785, COSV100866380; called by muse, varscan2
- SYT17 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs918035715, COSV100810706; called by muse, mutect2, varscan2
- TAF1 | c.2407C>T p.R803W (on ENST00000373790 / NM_138923.4; = p.R824W on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52111811; called by muse, mutect2, varscan2
- TALDO1 | c.219C>T p.G73= | Splice Region (SNP) | VAF 5/12 reads (42%) | catalogued as rs1281224073, COSV100032638; called by muse, mutect2, varscan2
- TAX1BP3 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs117575113; called by muse, mutect2, varscan2
- TBC1D1 | c.1545T>C p.G515= | Splice Region (SNP) | VAF 5/66 reads (8%) | catalogued as COSV99791188; called by muse, mutect2
- TBC1D16 | c.1273G>A p.G425S | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV60481643; called by muse, mutect2, varscan2
- TCP1 | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.178); catalogued as rs777545486, COSV58457896; called by muse, mutect2, varscan2
- TCP11L2 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as rs772592153, COSV54431314; called by muse, mutect2, varscan2
- TCP11L2 | c.580C>T p.R194* | Nonsense Mutation (SNP) | VAF 30/80 reads (38%) | catalogued as rs1472169592, COSV54432404; called by muse, mutect2, varscan2
- TEDC1 | c.1402C>T p.R468* (on ENST00000392523 / NM_001367178.1; = p.R399* on NM_001134875.1) | Nonsense Mutation (SNP) | VAF 6/13 reads (46%) | catalogued as rs139986633; called by muse, mutect2, varscan2
- TENM4 | c.5104C>T p.R1702C | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs766235028, COSV99574415; called by muse, mutect2, varscan2
- TENT4A | c.799C>T p.R267W | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100048909; called by muse, mutect2, varscan2
- TENT4B | c.704G>A p.R235Q (on ENST00000561678 / NM_001365323.2; = p.R220Q on NM_001040284.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770123017, COSV62548292; called by muse, mutect2, varscan2
- TEP1 | c.6847G>A p.V2283I | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs141111607; called by muse, mutect2, varscan2
- TFAP2E | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1366953216, COSV64696914; called by muse, mutect2, varscan2
- TG | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.88); PolyPhen benign (0.019); catalogued as rs759789389, COSV99600793; called by muse, mutect2, varscan2
- TG | c.7664G>A p.R2555H | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.677); catalogued as rs373473584; called by mutect2, varscan2
- TIFAB | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs376557001; called by muse, varscan2
- TIGD4 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as rs200034910; called by muse, mutect2, varscan2
- TLN2 | c.3443C>T p.A1148V | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as rs768697506, COSV60894731; called by muse, mutect2, varscan2
- TMEM132E | c.2069G>T p.G690V (on ENST00000321639; = p.G780V on NM_001304438.2) | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100396262; called by muse, mutect2, varscan2
- TMEM139 | c.88G>A p.G30S | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.028); catalogued as COSV100130992; called by muse, mutect2, varscan2
- TMEM201 | c.164C>T p.T55M | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759038883, COSV100440411; called by muse, mutect2, varscan2
- TMEM207 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs751631632, COSV61561696; called by muse, mutect2, varscan2
- TMEM254 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs749053952, COSV100953557; called by muse, mutect2, varscan2
- TMEM255A | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs782600983, COSV59028934; called by muse, mutect2, varscan2
- TMEM59L | c.911T>C p.L304P | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV53242101; called by muse, mutect2, varscan2
- TNC | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs141281085; called by muse, mutect2, varscan2
- TNIK | c.2443C>T p.R815W | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs181528556, COSV99457150; called by muse, mutect2, varscan2
- TNPO2 | c.1777G>A p.A593T | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as COSV63509914; called by muse, mutect2, varscan2
- TNRC18 | c.6304C>T p.R2102C | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs765959329, COSV60308694; called by muse, mutect2, varscan2
- TNRC6B | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100109672; called by muse, mutect2, varscan2
- TNS1 | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.24); catalogued as rs1399156741, COSV50746685; called by muse, mutect2, varscan2
- TNXB | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1378061730, COSV64479528; called by muse, mutect2
- TP63 | c.578C>T p.T193M | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53217852; called by muse, mutect2
- TPPP2 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.881); catalogued as rs143975728, COSV58794845; called by muse, mutect2, varscan2
- TPSD1 | c.175G>A p.G59S | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT tolerated (0.68); PolyPhen benign (0.038); catalogued as rs747525614, COSV99273847; called by muse, mutect2, varscan2
- TPST1 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.884); catalogued as rs375508551; called by muse, mutect2, varscan2
- TRAF3IP1 | c.1018T>G p.L340V | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.64); PolyPhen benign (0.031); catalogued as COSV100966863; called by muse, mutect2, varscan2
- TRBV2 | c.16G>A p.V6I | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs749183413; called by muse, mutect2, varscan2
- TRIB1 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs138022510; called by muse, mutect2, varscan2
- TRMT5 | c.50T>C p.L17P | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.241); catalogued as COSV99712108; called by muse, mutect2, varscan2
- TRPM3 | c.2959C>T p.R987C (on ENST00000357533 / NM_001366142.2; = p.R830C on NM_020952.6) | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775696679, COSV100677283; called by muse, mutect2, varscan2
- TSHZ3 | c.1099G>A p.G367S | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs777524623, COSV53668881, COSV99552976; called by muse, mutect2, varscan2
- TSPAN12 | c.285G>T p.W95C | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99763162; called by muse, mutect2, varscan2
- TTBK2 | c.3277C>T p.R1093C | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs375644796; called by muse, mutect2, varscan2
- TTC38 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs374547791, COSV101123887; called by muse, mutect2, varscan2
- TTI1 | c.2839C>T p.R947W | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372246998; called by muse, mutect2, varscan2
- TTLL3 | c.2071C>T p.R691W | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs368233188, COSV100047502; called by muse, varscan2
395 further variants in this file (70 protein-altering or splice-affecting, 306 silent, 19 other) are not listed here.
